Somatic mutation profile of tumor specimen ALCH-B3B0-TTP1-A (aliquot ALCH-B3B0-TTP1-A-1-0-D-A80C-36) from ALCHEMIST case ALCH-B3B0, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 77.1 years (28,163 days).
Specimen ALCH-B3B0-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d26f8065-2976-4117-aa46-b1f63c2faf08.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B3B0-NB1-A (Blood Derived Normal), aliquot ALCH-B3B0-NB1-A-1-0-D-A80C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/00e2c2f1-2c3f-4f5f-91da-728bcdad18cd

The open-access MAF lists 254 somatic variants for this specimen: 172 protein-altering or splice-affecting, 57 silent, 25 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 141, Silent 57, Nonsense Mutation 18, Intron 9, Splice Site 9, RNA 6, 3'UTR 4, 5'Flank 3, 5'UTR 2, Frame Shift Del 2, Splice Region 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.313G>T p.G105C | Missense Mutation (SNP) | VAF 13/78 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM043949, COSV52726068, COSV52741717, COSV53015551; called by muse, mutect2, varscan2
- AACS | c.1895G>T p.G632V | Missense Mutation (SNP) | VAF 10/97 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55538195; called by muse, mutect2
- AFM | c.1793G>T p.G598V | Missense Mutation (SNP) | VAF 27/226 reads (12%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as rs1308025899; called by muse, mutect2, varscan2
- APCS | c.362C>G p.S121* | Nonsense Mutation (SNP) | VAF 10/226 reads (4%) | catalogued as COSV54817288; called by muse, mutect2
- B3GNT3 | c.510C>A p.H170Q | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as COSV59438400; called by muse, mutect2, varscan2
- CARD14 | c.1157G>T p.R386L | Missense Mutation (SNP) | VAF 14/156 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs535721220, COSV60122714, COSV60123722; called by muse, mutect2
- CNGA3 | c.1115C>T p.P372L | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV55627747; called by muse, mutect2, varscan2
- CNTNAP2 | c.791C>G p.S264* | Nonsense Mutation (SNP) | VAF 18/364 reads (5%) | catalogued as COSV62171055; called by muse, mutect2
- DNMBP | c.3848G>C p.R1283T | Missense Mutation (SNP) | VAF 8/122 reads (7%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.996); catalogued as COSV60628796; called by muse, mutect2
- DOCK9 | c.5018G>T p.R1673L (on ENST00000376460 / NM_001366676.2; = p.R1674L on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/109 reads (10%) | SIFT tolerated (0.69); PolyPhen benign (0.003); catalogued as rs771873585; called by muse, mutect2, varscan2
- DSCAM | c.3521G>T p.G1174V | Missense Mutation (SNP) | VAF 7/143 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV68027533; called by muse, mutect2
- ERBB4 | c.2305G>A p.A769T | Missense Mutation (SNP) | VAF 8/179 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1169977608, COSV61521988; called by muse, mutect2
- FAT1 | c.10415A>G p.N3472S | Missense Mutation (SNP) | VAF 7/206 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1442180181; called by muse, mutect2
- FLNC | c.1076T>C p.I359T | Missense Mutation (SNP) | VAF 22/398 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1340028056; called by muse, mutect2
- FOXN4 | c.1324G>T p.G442* | Nonsense Mutation (SNP) | VAF 10/144 reads (7%) | catalogued as COSV54493535; called by muse, mutect2
- FRYL | c.2104A>T p.T702S | Missense Mutation (SNP) | VAF 30/319 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.341); catalogued as rs1406505868; called by muse, mutect2
- HOXD10 | c.514G>A p.G172S | Missense Mutation (SNP) | VAF 8/138 reads (6%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as COSV50906376; called by muse, mutect2
- HOXD9 | c.520G>T p.A174S | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs1015721717; called by muse, mutect2, varscan2
- KRT35 | c.1277G>A p.C426Y | Missense Mutation (SNP) | VAF 25/149 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.052); catalogued as rs1327810469; called by muse, mutect2, varscan2
- LAMA5 | c.1135G>C p.A379P | Missense Mutation (SNP) | VAF 17/133 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV53376734; called by muse, mutect2, varscan2
- LRP2 | c.7805G>C p.G2602A | Missense Mutation (SNP) | VAF 24/420 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.325); catalogued as COSV55550356; called by muse, mutect2
- LRRC72 | c.565A>G p.K189E | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV69129863; called by muse, mutect2, varscan2
- MOXD1 | c.81C>A p.H27Q | Missense Mutation (SNP) | VAF 8/200 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); catalogued as rs867037582, COSV63454026; called by muse, mutect2
- MSLNL | c.470G>A p.W157* | Nonsense Mutation (SNP) | VAF 7/85 reads (8%) | catalogued as rs867054224; called by muse, mutect2
- NLRP13 | c.3067G>T p.D1023Y | Missense Mutation (SNP) | VAF 10/146 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.324); catalogued as COSV61620933; called by muse, mutect2
- OR2M3 | c.461C>A p.T154K | Missense Mutation (SNP) | VAF 10/254 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.161); catalogued as COSV101513446, COSV71759086; called by muse, mutect2
- OR4A15 | c.755G>C p.C252S | Missense Mutation (SNP) | VAF 7/117 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.951); catalogued as rs1238905074, COSV100123896; called by muse, mutect2
- OR4S2 | c.116G>T p.G39V | Missense Mutation (SNP) | VAF 18/183 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56746257; called by muse, mutect2
- OR4X1 | c.535G>T p.V179F | Missense Mutation (SNP) | VAF 9/137 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.938); catalogued as COSV60722567; called by muse, mutect2
- PCDH15 | c.1029G>T p.R343S | Missense Mutation (SNP) | VAF 10/296 reads (3%) | SIFT tolerated (0.8); PolyPhen benign (0.013); catalogued as COSV57386419; called by muse, mutect2
- PKHD1L1 | c.1640A>G p.Y547C | Missense Mutation (SNP) | VAF 19/148 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.619); catalogued as rs1344017315; called by muse, varscan2
- PPARD | c.868A>G p.I290V | Missense Mutation (SNP) | VAF 17/210 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs1183119482; called by muse, mutect2
- PPARD | c.1289A>G p.H430R | Missense Mutation (SNP) | VAF 16/183 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.229); catalogued as COSV100282987; called by muse, mutect2
- SIGLEC8 | c.1210G>A p.E404K | Missense Mutation (SNP) | VAF 22/204 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as COSV58472035, COSV58474761; called by muse, mutect2
- SLC17A2 | c.475G>T p.G159* | Nonsense Mutation (SNP) | VAF 16/208 reads (8%) | catalogued as rs1442616349; called by muse, mutect2
- SLC5A6 | c.11G>A p.G4E | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as rs1349797352; called by muse, mutect2, varscan2
- SMARCA4 | c.2372C>T p.A791V | Missense Mutation (SNP) | VAF 22/219 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as rs1263140481, COSV60786575; called by mutect2, varscan2
- TBP | c.1010A>G p.K337R | Missense Mutation (SNP) | VAF 14/345 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.889); catalogued as COSV57833046; called by muse, mutect2
- TRIM77 | c.1095G>T p.R365S | Missense Mutation (SNP) | VAF 12/204 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0.01); catalogued as rs1027747741, COSV68066318; called by muse, mutect2
- TRIM9 | c.1591C>T p.Q531* | Nonsense Mutation (SNP) | VAF 16/264 reads (6%) | catalogued as rs1414802288; called by muse, mutect2
- TRMT61B | c.806G>A p.G269E | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV60258601; called by muse, mutect2, varscan2
- TRRAP | c.9584C>T p.S3195L (on ENST00000359863 / NM_001244580.1; = p.S3166L on NM_003496.3) | Missense Mutation (SNP) | VAF 9/160 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.788); catalogued as COSV62843588; called by muse, mutect2
- TTN | c.6712A>G p.T2238A (on ENST00000591111; = p.T2192A on NM_003319.4) | Missense Mutation (SNP) | VAF 27/206 reads (13%) | PolyPhen benign (0); catalogued as rs747377115; called by muse, mutect2, varscan2
- UNC13A | c.288G>T p.W96C | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV53208657; called by muse, mutect2
- USH2A | c.9053G>T p.G3018V | Missense Mutation (SNP) | VAF 20/444 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV56423068; called by muse, mutect2
- USH2A | c.9052G>T p.G3018W | Missense Mutation (SNP) | VAF 20/446 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100236750; called by muse, mutect2
- USP17L7 | c.486T>G p.H162Q | Missense Mutation (SNP) | VAF 16/579 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs1208176064; called by muse, mutect2
- USP17L7 | c.484C>A p.H162N | Missense Mutation (SNP) | VAF 16/578 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV61556489; called by muse, mutect2
- VSIG4 | c.253C>T p.R85C | Missense Mutation (SNP) | VAF 15/215 reads (7%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs747618819, COSV66073183; called by muse, mutect2
- ZIM3 | c.453C>G p.Y151* | Nonsense Mutation (SNP) | VAF 13/130 reads (10%) | catalogued as COSV54145471; called by muse, mutect2, varscan2
- ZNF438 | c.335C>T p.S112F | Missense Mutation (SNP) | VAF 10/302 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); catalogued as COSV100062943; called by muse, mutect2
- ABCC12 | c.3360C>G p.I1120M | Missense Mutation (SNP) | VAF 14/180 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- ABLIM3 | c.336-2A>T p.X112_splice | Splice Site (SNP) | VAF 7/134 reads (5%) | called by muse, mutect2
- AC244258.1 | n.624-1G>T | Splice Site (SNP) | VAF 14/152 reads (9%) | called by muse, mutect2, varscan2
- ACSBG1 | c.1047C>G p.C349W | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2
- ACTRT1 | c.911C>A p.T304N | Missense Mutation (SNP) | VAF 16/197 reads (8%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.597); called by muse, mutect2
- ALS2 | c.2956A>T p.I986F | Missense Mutation (SNP) | VAF 24/512 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.028); called by muse, mutect2
- AMER3 | c.1082G>T p.G361V | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- ANKRD52 | c.877G>T p.V293F | Missense Mutation (SNP) | VAF 9/142 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2
- ANP32B | c.362T>G p.F121C | Missense Mutation (SNP) | VAF 8/156 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ANXA5 | c.820G>C p.V274L | Missense Mutation (SNP) | VAF 16/268 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- APBA1 | c.1886A>T p.K629M | Missense Mutation (SNP) | VAF 18/242 reads (7%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.751); called by muse, mutect2
- ARHGAP33 | c.1889C>G p.T630R | Missense Mutation (SNP) | VAF 10/198 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.839); called by muse, mutect2
- ATP1A2 | c.2477G>T p.S826I | Missense Mutation (SNP) | VAF 28/320 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2
- C14orf93 | c.1073A>G p.K358R | Missense Mutation (SNP) | VAF 17/180 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2
- CA13 | c.372G>T p.W124C | Missense Mutation (SNP) | VAF 32/310 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CA8 | c.632T>C p.L211P | Missense Mutation (SNP) | VAF 34/512 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- CCDC170 | c.1616A>T p.Q539L | Missense Mutation (SNP) | VAF 12/377 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.076); called by muse, mutect2
- CCNB3 | c.1860G>T p.K620N | Missense Mutation (SNP) | VAF 9/204 reads (4%) | SIFT tolerated (0.19); PolyPhen benign (0.056); called by muse, mutect2
- CDH2 | c.2128A>G p.T710A | Missense Mutation (SNP) | VAF 20/430 reads (5%) | SIFT tolerated (0.31); PolyPhen benign (0.017); called by muse, mutect2
- CLASP2 | c.2458-1G>T p.X820_splice | Splice Site (SNP) | VAF 8/119 reads (7%) | called by muse, mutect2
- COBL | c.3164G>T p.G1055V | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT tolerated (0.65); PolyPhen benign (0.003); called by muse, mutect2
- COL4A4 | c.1988-2A>T p.X663_splice | Splice Site (SNP) | VAF 20/396 reads (5%) | called by muse, mutect2
- CPN1 | c.425C>A p.P142Q | Missense Mutation (SNP) | VAF 20/355 reads (6%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.454); called by muse, mutect2
- CPNE2 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 3/41 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.838); called by muse, mutect2
- CR1L | c.817C>A p.Q273K | Missense Mutation (SNP) | VAF 15/321 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.449); called by muse, mutect2
- CSMD2 | c.9570C>G p.C3190W | Missense Mutation (SNP) | VAF 10/292 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CWF19L2 | c.2033G>T p.C678F | Missense Mutation (SNP) | VAF 18/414 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DKC1 | c.73G>C p.E25Q | Missense Mutation (SNP) | VAF 12/307 reads (4%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.007); called by muse, mutect2
- DNAJB11 | c.235G>C p.D79H | Missense Mutation (SNP) | VAF 7/115 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- DNM1 | c.1467C>G p.N489K | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.877); called by muse, mutect2
- DSPP | c.1444G>C p.D482H | Missense Mutation (SNP) | VAF 47/918 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.813); called by muse, mutect2
- ECRG4 | c.355T>C p.Y119H | Missense Mutation (SNP) | VAF 10/205 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0.005); called by muse, mutect2
- EDA2R | c.307G>A p.E103K | Missense Mutation (SNP) | VAF 7/111 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.175); called by muse, mutect2
- FANCL | c.133G>T p.D45Y | Missense Mutation (SNP) | VAF 27/326 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- FGFR2 | c.1972A>T p.K658* | Nonsense Mutation (SNP) | VAF 26/374 reads (7%) | called by muse, mutect2
- FHOD3 | c.756G>T p.E252D | Missense Mutation (SNP) | VAF 15/284 reads (5%) | SIFT tolerated (0.23); PolyPhen benign (0.001); called by muse, mutect2
- FMN1 | c.1548G>T p.Q516H | Missense Mutation (SNP) | VAF 13/263 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.172); called by muse, mutect2
- FTSJ3 | c.389C>G p.A130G | Missense Mutation (SNP) | VAF 36/194 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- GABRB3 | c.992T>A p.F331Y | Missense Mutation (SNP) | VAF 28/416 reads (7%) | SIFT tolerated (0.69); PolyPhen benign (0.05); called by muse, mutect2
- GPR85 | c.674G>C p.S225T | Missense Mutation (SNP) | VAF 12/176 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- HGF | c.1349C>T p.P450L | Missense Mutation (SNP) | VAF 12/312 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- HHATL | c.649T>A p.F217I | Missense Mutation (SNP) | VAF 27/263 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- HMCN1 | c.5144C>G p.T1715S | Missense Mutation (SNP) | VAF 11/162 reads (7%) | SIFT tolerated (0.65); PolyPhen probably damaging (0.994); called by muse, mutect2
- HOXB2 | c.671C>A p.P224H | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.156); called by muse, mutect2, varscan2
- HPS5 | c.1013A>G p.N338S (on ENST00000349215 / NM_181507.2; = p.N224S on NM_007216.4) | Missense Mutation (SNP) | VAF 12/346 reads (3%) | SIFT tolerated (0.29); PolyPhen benign (0.024); called by muse, mutect2
- IGSF22 | c.65C>A p.T22N | Missense Mutation (SNP) | VAF 12/131 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.121); called by muse, mutect2
- ITGA10 | c.1396A>G p.K466E | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT tolerated (0.48); PolyPhen benign (0.146); called by muse, mutect2
- KCND2 | c.1271C>T p.A424V | Missense Mutation (SNP) | VAF 20/266 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); called by muse, mutect2
- KCNH5 | c.1486C>G p.Q496E | Missense Mutation (SNP) | VAF 28/494 reads (6%) | SIFT tolerated (0.32); PolyPhen benign (0.109); called by muse, mutect2
- KEAP1 | c.407T>C p.L136P | Missense Mutation (SNP) | VAF 17/210 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- KIT | c.2744C>G p.P915R | Missense Mutation (SNP) | VAF 34/528 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2
- KLHL22 | c.1346A>G p.Y449C | Missense Mutation (SNP) | VAF 12/204 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2
- KLHL4 | c.1457G>T p.G486V | Missense Mutation (SNP) | VAF 10/197 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- KRTAP7-1 | c.94T>A p.C32S | Missense Mutation (SNP) | VAF 27/257 reads (11%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- LILRA5 | c.251C>A p.P84Q | Missense Mutation (SNP) | VAF 34/299 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- LILRA5 | c.250C>A p.P84T | Missense Mutation (SNP) | VAF 33/296 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- LILRB3 | c.629C>A p.P210H | Missense Mutation (SNP) | VAF 10/208 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- LPAR4 | c.349G>T p.A117S | Missense Mutation (SNP) | VAF 15/240 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.288); called by muse, mutect2
- LRFN5 | c.1987G>A p.V663I | Missense Mutation (SNP) | VAF 19/296 reads (6%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); called by muse, mutect2
- LRP1B | c.10534C>A p.P3512T | Missense Mutation (SNP) | VAF 22/199 reads (11%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.617); called by muse, mutect2, varscan2
- MAGEB5 | c.562G>T p.E188* | Nonsense Mutation (SNP) | VAF 10/171 reads (6%) | called by muse, mutect2
- MAGEF1 | c.346G>A p.D116N | Missense Mutation (SNP) | VAF 18/382 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.042); called by muse, mutect2
- MED25 | c.1033A>T p.S345C | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); called by muse, mutect2
- MS4A18 | c.155G>T p.C52F | Missense Mutation (SNP) | VAF 22/390 reads (6%) | SIFT tolerated (0.67); PolyPhen benign (0.025); called by muse, mutect2
- MUC16 | c.22832C>A p.S7611Y | Missense Mutation (SNP) | VAF 16/200 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.027); called by muse, mutect2
- MYH8 | c.4028G>T p.C1343F | Missense Mutation (SNP) | VAF 30/450 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.033); called by muse, mutect2
- MYOM1 | c.2993T>G p.I998S | Missense Mutation (SNP) | VAF 10/138 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); called by muse, mutect2
- NCOA1 | c.444G>T p.Q148H | Missense Mutation (SNP) | VAF 13/201 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); called by muse, mutect2
- NIPAL2 | c.944+1G>T p.X315_splice | Splice Site (SNP) | VAF 14/294 reads (5%) | called by muse, mutect2
- NPHS1 | c.3107C>A p.P1036Q | Missense Mutation (SNP) | VAF 24/219 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.497); called by muse, mutect2, varscan2
- NPY2R | c.453C>A p.C151* | Nonsense Mutation (SNP) | VAF 14/134 reads (10%) | called by muse, mutect2
- NR2E1 | c.26-2A>T p.X9_splice | Splice Site (SNP) | VAF 10/172 reads (6%) | called by muse, mutect2
- NUFIP2 | c.116A>T p.Y39F | Missense Mutation (SNP) | VAF 20/286 reads (7%) | SIFT tolerated, low confidence (0.58); PolyPhen probably damaging (0.971); called by muse, mutect2
- OBSCN | c.18265G>T p.A6089S | Missense Mutation (SNP) | VAF 12/128 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- OR2B3 | c.397G>T p.V133L | Missense Mutation (SNP) | VAF 10/267 reads (4%) | SIFT tolerated (0.18); PolyPhen benign (0.007); called by muse, mutect2
- OR8H3 | c.605T>C p.I202T | Missense Mutation (SNP) | VAF 10/176 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.009); called by muse, mutect2
- OR9Q1 | c.656T>A p.L219Q | Missense Mutation (SNP) | VAF 12/202 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2
- OTOG | c.6519G>T p.M2173I | Missense Mutation (SNP) | VAF 11/297 reads (4%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, mutect2
- PBRM1 | c.3066T>A p.Y1022* (on ENST00000296302 / NM_001366071.2; = p.Y997* on NM_018313.5) | Nonsense Mutation (SNP) | VAF 16/222 reads (7%) | called by muse, mutect2
- PDE8B | c.1784C>G p.T595S | Missense Mutation (SNP) | VAF 13/295 reads (4%) | SIFT tolerated (0.91); PolyPhen benign (0.001); called by muse, mutect2
- PDZRN3 | c.1906C>A p.L636M | Missense Mutation (SNP) | VAF 11/267 reads (4%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.876); called by muse, mutect2
- PKP2 | c.2524G>C p.V842L | Missense Mutation (SNP) | VAF 30/542 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.347); called by muse, mutect2
- PLOD1 | c.1934A>G p.Y645C | Missense Mutation (SNP) | VAF 18/286 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2
- POM121L12 | c.343G>T p.A115S | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT tolerated (0.53); PolyPhen benign (0.441); called by muse, mutect2
- POTEA | c.180C>A p.H60Q | Missense Mutation (SNP) | VAF 25/263 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.218); called by muse, mutect2, varscan2
- POTEH | c.6_7del p.A3* | Frame Shift Del (DEL) | VAF 10/92 reads (11%) | called by mutect2, varscan2
- PRAMEF15 | c.1384G>C p.D462H | Missense Mutation (SNP) | VAF 10/285 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- PRDM14 | c.1252C>A p.H418N | Missense Mutation (SNP) | VAF 32/217 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PRKG1 | c.726A>T p.E242D | Missense Mutation (SNP) | VAF 10/234 reads (4%) | SIFT tolerated (0.13); PolyPhen benign (0.003); called by muse, mutect2
- PRSS3 | c.267+1G>A p.X89_splice (on ENST00000361005 / NM_007343.4; = p.X197_splice on NM_002771.3) | Splice Site (SNP) | VAF 10/203 reads (5%) | called by muse, mutect2
- PRSS35 | c.898A>T p.K300* | Nonsense Mutation (SNP) | VAF 21/321 reads (7%) | called by muse, mutect2
- PTCHD1 | c.1637A>C p.Q546P | Missense Mutation (SNP) | VAF 34/605 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.841); called by muse, mutect2
- PTPRC | c.1512G>T p.K504N | Missense Mutation (SNP) | VAF 29/394 reads (7%) | SIFT tolerated (0.33); PolyPhen benign (0.029); called by muse, mutect2
- R3HDM1 | c.1150G>T p.G384* | Nonsense Mutation (SNP) | VAF 28/328 reads (9%) | called by muse, mutect2
- RAF1 | c.1761C>G p.D587E | Missense Mutation (SNP) | VAF 34/378 reads (9%) | SIFT tolerated (0.28); PolyPhen benign (0.274); called by muse, mutect2
- RGS12 | c.1291C>T p.Q431* | Nonsense Mutation (SNP) | VAF 10/167 reads (6%) | called by muse, mutect2
- SARDH | c.2738G>T p.R913M | Missense Mutation (SNP) | VAF 16/147 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, varscan2
- SLA2 | c.442T>A p.Y148N | Missense Mutation (SNP) | VAF 14/368 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SLC4A10 | c.2862G>A p.Q954= (on ENST00000446997 / NM_001354461.2; = p.Q924= on NM_022058.4 and 5 other RefSeq transcripts) | Splice Region (SNP) | VAF 10/147 reads (7%) | called by muse, mutect2
- SLC5A12 | c.152G>T p.G51V | Missense Mutation (SNP) | VAF 22/374 reads (6%) | SIFT tolerated (0.77); PolyPhen benign (0.124); called by muse, mutect2
- SLIT3 | c.1267T>A p.F423I | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2
- SNX9 | c.649G>T p.E217* | Nonsense Mutation (SNP) | VAF 12/186 reads (6%) | called by muse, mutect2
- SPANXN1 | c.103G>A p.A35T | Missense Mutation (SNP) | VAF 28/220 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- SPEF2 | c.1186A>G p.K396E | Missense Mutation (SNP) | VAF 18/170 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- SSC5D | c.2204A>T p.Q735L | Missense Mutation (SNP) | VAF 20/214 reads (9%) | SIFT tolerated (0.44); PolyPhen benign (0); called by muse, mutect2
- STAC2 | c.942-2A>T p.X314_splice | Splice Site (SNP) | VAF 8/164 reads (5%) | called by muse, mutect2
- STXBP5L | c.1774G>T p.G592W | Missense Mutation (SNP) | VAF 22/244 reads (9%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.916); called by muse, mutect2
- TKTL2 | c.1799G>A p.G600E | Missense Mutation (SNP) | VAF 3/50 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2
- TLL1 | c.328C>T p.Q110* | Nonsense Mutation (SNP) | VAF 20/340 reads (6%) | called by muse, mutect2
- TOR1AIP2 | c.22G>C p.E8Q | Missense Mutation (SNP) | VAF 27/362 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.034); called by muse, mutect2
- TRAF6 | c.1117G>T p.V373F | Missense Mutation (SNP) | VAF 8/194 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.528); called by muse, mutect2
- UCP3 | c.644A>G p.D215G | Missense Mutation (SNP) | VAF 24/313 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.627); called by muse, mutect2
- UNC13A | c.287G>T p.W96L | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.984); called by muse, mutect2
- UPF2 | c.841A>T p.K281* | Nonsense Mutation (SNP) | VAF 29/230 reads (13%) | called by muse, mutect2, varscan2
- USP24 | c.2056G>T p.V686L | Missense Mutation (SNP) | VAF 15/407 reads (4%) | SIFT tolerated (0.38); PolyPhen benign (0.005); called by muse, mutect2
- VSIG10 | c.1141_1148del p.L381Gfs*8 | Frame Shift Del (DEL) | VAF 16/130 reads (12%) | called by mutect2, pindel, varscan2
- ZFYVE1 | c.91A>T p.I31F | Missense Mutation (SNP) | VAF 16/154 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ZNF221 | c.1466G>T p.W489L | Missense Mutation (SNP) | VAF 12/316 reads (4%) | SIFT tolerated (0.19); PolyPhen benign (0.185); called by muse, mutect2
- ZNF644 | c.2136A>T p.K712N | Missense Mutation (SNP) | VAF 20/439 reads (5%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.348); called by muse, mutect2
- ZNF729 | c.192T>A p.C64* | Nonsense Mutation (SNP) | VAF 19/204 reads (9%) | called by muse, mutect2
- ZNF805 | c.31-2A>C p.X11_splice | Splice Site (SNP) | VAF 22/329 reads (7%) | called by muse, mutect2
- ANK1 | c.4347C>G p.A1449= | Silent (SNP) | VAF 16/427 reads (4%) | called by muse, mutect2
- ANKRD30A | c.1248G>A p.K416= (on ENST00000611781; = p.K360= on NM_052997.2) | Silent (SNP) | VAF 25/400 reads (6%) | called by muse, mutect2
- ANTXR1 | c.1263G>T p.P421= | Silent (SNP) | VAF 46/468 reads (10%) | called by muse, mutect2, varscan2
- CBR1 | c.432C>A p.V144= | Silent (SNP) | VAF 8/94 reads (9%) | called by muse, mutect2
- CFAP92 | c.2562C>A p.P854= | Silent (SNP) | VAF 30/422 reads (7%) | called by muse, mutect2
- COL15A1 | c.1456C>T p.L486= | Silent (SNP) | VAF 10/236 reads (4%) | catalogued as rs1319995139; called by muse, mutect2
- CSGALNACT1 | c.39C>T p.S13= | Silent (SNP) | VAF 18/346 reads (5%) | called by muse, mutect2
- DNA2 | c.3105A>T p.S1035= | Silent (SNP) | VAF 6/144 reads (4%) | called by muse, mutect2
- EEF2K | c.564G>A p.Q188= | Silent (SNP) | VAF 12/182 reads (7%) | called by muse, mutect2
- FAT4 | c.4758G>T p.V1586= | Silent (SNP) | VAF 10/150 reads (7%) | catalogued as COSV67888754; called by muse, mutect2
- FCGBP | c.2526G>T p.P842= | Silent (SNP) | VAF 4/62 reads (6%) | called by muse, mutect2
- FRY | c.753A>G p.L251= | Silent (SNP) | VAF 34/331 reads (10%) | catalogued as rs1303168833; called by muse, mutect2, varscan2
- FSHR | c.498G>A p.V166= | Silent (SNP) | VAF 34/564 reads (6%) | called by muse, mutect2
- GALM | c.756A>G p.K252= | Silent (SNP) | VAF 13/122 reads (11%) | called by muse, mutect2, varscan2
- GBA3 | c.1371C>T p.A457= | Silent (SNP) | VAF 9/212 reads (4%) | catalogued as COSV72438173; called by muse, mutect2
- GPD1 | c.684C>A p.I228= | Silent (SNP) | VAF 18/264 reads (7%) | called by muse, mutect2
- HACE1 | c.150A>G p.L50= | Silent (SNP) | VAF 38/583 reads (7%) | catalogued as rs1162790681; called by muse, mutect2
- HEG1 | c.699G>A p.E233= | Silent (SNP) | VAF 11/174 reads (6%) | called by muse, mutect2
- IGF1R | c.66G>T p.A22= | Silent (SNP) | VAF 34/298 reads (11%) | catalogued as COSV51270402; called by muse, mutect2, varscan2
- IGFBP1 | c.189C>T p.C63= | Silent (SNP) | VAF 12/183 reads (7%) | called by muse, mutect2
- INTS8 | c.690A>C p.V230= | Silent (SNP) | VAF 32/329 reads (10%) | called by muse, mutect2
- ITGBL1 | c.130C>A p.R44= | Silent (SNP) | VAF 3/19 reads (16%) | called by muse, mutect2
- ITPRIPL1 | c.771C>T p.A257= (on ENST00000439118 / NM_001008949.3; = p.A265= on NM_178495.6) | Silent (SNP) | VAF 9/56 reads (16%) | called by muse, mutect2, varscan2
- KEAP1 | c.408C>T p.L136= | Silent (SNP) | VAF 17/211 reads (8%) | catalogued as rs773199037; called by muse, mutect2
- KIF13B | c.1107G>T p.R369= | Silent (SNP) | VAF 16/250 reads (6%) | called by muse, mutect2
- LRCH4 | c.390A>C p.P130= | Silent (SNP) | VAF 12/211 reads (6%) | called by muse, mutect2
- MYCL | c.699C>T p.P233= | Silent (SNP) | VAF 12/242 reads (5%) | catalogued as rs1384181191; called by muse, mutect2
- MYO7B | c.4479C>A p.A1493= | Silent (SNP) | VAF 16/174 reads (9%) | called by muse, mutect2
- NDST4 | c.780G>A p.L260= | Silent (SNP) | VAF 16/228 reads (7%) | called by muse, mutect2
- OCSTAMP | c.547C>A p.R183= | Silent (SNP) | VAF 21/137 reads (15%) | called by muse, mutect2, varscan2
- OR2AG2 | c.348C>A p.A116= | Silent (SNP) | VAF 18/252 reads (7%) | called by muse, mutect2
- PGBD4 | c.639T>C p.S213= | Silent (SNP) | VAF 12/272 reads (4%) | called by muse, mutect2
- PKNOX2 | c.756C>A p.S252= | Silent (SNP) | VAF 12/188 reads (6%) | called by muse, mutect2
- PLTP | c.786G>A p.R262= | Silent (SNP) | VAF 11/214 reads (5%) | catalogued as rs1205096439, COSV100819113; called by muse, mutect2
- PRPF40B | c.1575T>A p.T525= (on ENST00000380281; = p.T519= on NM_012272.3) | Silent (SNP) | VAF 18/298 reads (6%) | called by muse, mutect2
- PRR16 | c.123G>T p.L41= | Silent (SNP) | VAF 9/122 reads (7%) | called by muse, mutect2
- PTCRA | c.474C>T p.F158= | Silent (SNP) | VAF 11/288 reads (4%) | called by muse, mutect2
- PTPRQ | c.1635G>A p.R545= (on ENST00000616559; = p.R503= on NM_001145026.2) | Silent (SNP) | VAF 12/120 reads (10%) | called by muse, mutect2, varscan2
- RYR2 | c.2850G>T p.V950= | Silent (SNP) | VAF 14/320 reads (4%) | catalogued as COSV63694548; called by muse, mutect2
- SCAPER | c.3303C>T p.D1101= | Silent (SNP) | VAF 8/98 reads (8%) | catalogued as rs1157063946; called by muse, mutect2
- SCN2A | c.5430C>A p.T1810= | Silent (SNP) | VAF 20/451 reads (4%) | called by muse, mutect2
- SHROOM3 | c.3639G>T p.G1213= | Silent (SNP) | VAF 16/162 reads (10%) | called by muse, mutect2
- SIGLEC14 | c.807C>T p.S269= | Silent (SNP) | VAF 10/51 reads (20%) | catalogued as rs746770970; called by muse, mutect2, varscan2
- SIGLEC8 | c.600C>T p.G200= | Silent (SNP) | VAF 10/81 reads (12%) | called by muse, mutect2, varscan2
- SLA | c.345C>A p.T115= (on ENST00000338087 / NM_001045556.3; = p.T155= on NM_006748.4) | Silent (SNP) | VAF 22/266 reads (8%) | called by muse, mutect2
- SLC30A8 | c.991C>A p.R331= | Silent (SNP) | VAF 30/386 reads (8%) | catalogued as rs1466795972, COSV69970593; called by muse, mutect2
- SLC6A19 | c.1479C>T p.P493= | Silent (SNP) | VAF 24/310 reads (8%) | catalogued as COSV58670834; called by muse, mutect2
- STAG1 | c.2319G>A p.L773= | Silent (SNP) | VAF 15/294 reads (5%) | called by muse, mutect2
- TARS2 | c.1665G>T p.G555= | Silent (SNP) | VAF 40/299 reads (13%) | called by muse, mutect2, varscan2
- TCHH | c.5439C>A p.R1813= | Silent (SNP) | VAF 16/179 reads (9%) | called by muse, mutect2
- TESK2 | c.120A>G p.P40= | Silent (SNP) | VAF 27/409 reads (7%) | catalogued as rs754182435; called by muse, mutect2
- TFRC | c.1269A>T p.T423= | Silent (SNP) | VAF 12/195 reads (6%) | called by muse, mutect2
- TLE5 | c.501C>G p.S167= | Silent (SNP) | VAF 8/125 reads (6%) | called by muse, mutect2
- TMPRSS5 | c.561G>A p.E187= | Silent (SNP) | VAF 8/137 reads (6%) | called by muse, mutect2
- TTC8 | c.1404A>G p.A468= (on ENST00000338104 / NM_001288781.1; = p.A452= on NM_144596.4) | Silent (SNP) | VAF 18/293 reads (6%) | called by muse, mutect2
- UGT2A1 | c.1365G>A p.L455= | Silent (SNP) | VAF 13/206 reads (6%) | catalogued as COSV54143192; called by muse, mutect2
- VENTX | c.681C>A p.S227= | Silent (SNP) | VAF 9/119 reads (8%) | called by muse, mutect2
- ABI2 | c.*14711T>C | 3'UTR (SNP) | VAF 3/46 reads (7%) | called by muse, mutect2
- AC018563.1 | n.680C>A | RNA (SNP) | VAF 7/60 reads (12%) | catalogued as rs1463962773; called by muse, mutect2, varscan2
- AC092687.1 | n.301T>C | RNA (SNP) | VAF 8/166 reads (5%) | called by muse, mutect2
- ANK1 | c.5395-350A>T | Intron (SNP) | VAF 15/208 reads (7%) | called by muse, mutect2
- AP003548.1 | n.372G>T | RNA (SNP) | VAF 12/287 reads (4%) | called by muse, mutect2
- ARHGEF25 | chr12:57610236 C>T | 5'Flank (SNP) | VAF 10/54 reads (19%) | called by muse, mutect2, varscan2
- CLCN6 | c.2529+122C>T | Intron (SNP) | VAF 16/166 reads (10%) | called by muse, mutect2
- EIF4E | c.19-7695G>T | Intron (SNP) | VAF 9/148 reads (6%) | called by muse, mutect2
- EIF4E | c.19-7696G>A | Intron (SNP) | VAF 9/152 reads (6%) | called by muse, mutect2
- GATA4 | chr8:11761547 C>A | 3'Flank (SNP) | VAF 5/79 reads (6%) | called by muse, mutect2
- GNAO1 | c.161+1642C>A | Intron (SNP) | VAF 11/197 reads (6%) | called by muse, mutect2
- HMGN1 | chr21:39349462 G>T | 5'Flank (SNP) | VAF 9/68 reads (13%) | called by muse, mutect2, varscan2
- HOXA2 | c.*41C>T | 3'UTR (SNP) | VAF 14/158 reads (9%) | catalogued as rs751247463, COSV99761023; called by muse, mutect2
- HSP90AA4P | n.2094G>T | RNA (SNP) | VAF 6/114 reads (5%) | called by muse, mutect2
- INMT-MINDY4 | c.*5C>A | 3'UTR (SNP) | VAF 6/152 reads (4%) | called by muse, mutect2
- KATNIP | c.540+5894A>T | Intron (SNP) | VAF 16/202 reads (8%) | called by muse, mutect2
- MARCHF1 | c.242+607A>G | Intron (SNP) | VAF 14/304 reads (5%) | called by muse, mutect2
- MINDY4 | chr7:30766417 C>A | 5'Flank (SNP) | VAF 6/148 reads (4%) | called by muse, mutect2
- MUC19 | n.23252A>T | RNA (SNP) | VAF 29/278 reads (10%) | called by muse, mutect2, varscan2
- NOC2LP2 | n.456G>T | RNA (SNP) | VAF 38/363 reads (10%) | called by muse, mutect2, varscan2
- NOD2 | c.-7G>A | 5'UTR (SNP) | VAF 21/305 reads (7%) | called by muse, mutect2
- PMFBP1 | c.*457A>G | 3'UTR (SNP) | VAF 11/190 reads (6%) | called by muse, mutect2
- SPEF2 | c.4448-3729A>G | Intron (SNP) | VAF 17/155 reads (11%) | called by muse, mutect2, varscan2
- TRHR | c.-16C>A | 5'UTR (SNP) | VAF 15/234 reads (6%) | called by muse, mutect2
- VIPR2 | c.152-7461C>A | Intron (SNP) | VAF 10/289 reads (3%) | called by muse, mutect2
